Somatic mutation profile of tumor specimen C3L-00004-01 (aliquot CPT0001540165) from CPTAC case C3L-00004, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 72.3 years (26,409 days).
Specimen C3L-00004-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 223130e5-b0b1-4dd7-ae3c-3af89cbf96b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00004-31 (Blood Derived Normal), aliquot CPT0000140163; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f229000-4a79-42f4-9bc2-a4176503356c

The open-access MAF lists 96 somatic variants for this specimen: 72 protein-altering or splice-affecting, 11 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 11, Intron 7, Nonsense Mutation 3, 5'Flank 3, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 1, RNA 1, 3'UTR 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACA | c.1984C>T p.R662* | Nonsense Mutation (SNP) | VAF 64/515 reads (12%) | catalogued as rs755352202; called by muse, mutect2, varscan2
- ASPM | c.7994G>C p.R2665P | Missense Mutation (SNP) | VAF 89/458 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs766267818; called by muse, mutect2, varscan2
- BOD1L1 | c.6908C>T p.A2303V | Missense Mutation (SNP) | VAF 70/349 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs996723621; called by muse, mutect2, varscan2
- CARD11 | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.216); catalogued as rs757553187; called by muse, mutect2, varscan2
- CEP250 | c.6775A>G p.S2259G | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV100698743; called by muse, mutect2, varscan2
- FCN1 | c.266C>A p.P89H | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV65662144; called by muse, mutect2, varscan2
- FN1 | c.3517+1G>A p.X1173_splice | Splice Site (SNP) | VAF 85/447 reads (19%) | catalogued as rs925967935; called by muse, mutect2, varscan2
- GPRIN2 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1262714639, COSV65400701; called by muse, mutect2
- IGKV1-12 | c.325T>C p.Y109H | Missense Mutation (SNP) | VAF 103/1011 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as rs1231157327; called by muse, mutect2, varscan2
- IMPG1 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.041); catalogued as rs370162508, COSV64055755; called by muse, mutect2, varscan2
- IRF2BP2 | c.1419G>T p.E473D | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as rs1291472581; called by muse, mutect2, varscan2
- MAN2A2 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 147/659 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1442531428; called by muse, mutect2, varscan2
- MRPL27 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as rs374090666; called by muse, mutect2, varscan2
- MTBP | c.2539A>G p.I847V | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV100011887; called by muse, mutect2, varscan2
- OR10H1 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771720675, COSV58470679; called by muse, mutect2, varscan2
- OR13H1 | c.403G>C p.V135L | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as rs776691014; called by muse, mutect2, varscan2
- PBRM1 | c.3028C>T p.R1010* | Nonsense Mutation (SNP) | VAF 37/143 reads (26%) | catalogued as COSV56258855; called by muse, mutect2, varscan2
- PKP3 | c.273C>G p.F91L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV100520862; called by muse, mutect2, varscan2
- SPATS1 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs762399024; called by muse, mutect2, varscan2
- TNRC6B | c.3004G>C p.G1002R (on ENST00000454349 / NM_001162501.2; = p.G949R on NM_015088.3) | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs778831852; called by muse, mutect2, varscan2
- VHL | c.388G>T p.V130F | Missense Mutation (SNP) | VAF 111/427 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104893830, CM031394, CM126148, CM961427, COSV56543368, COSV56544519, COSV56551325, COSV56566091; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AMBRA1 | c.2030A>T p.Q677L (on ENST00000458649 / NM_001367468.1; = p.Q587L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/348 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- ATP5F1B | c.496dup p.I166Nfs*4 | Frame Shift Ins (INS) | VAF 28/165 reads (17%) | called by mutect2, pindel, varscan2
- BLVRB | c.517T>G p.S173A | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- C18orf63 | c.1481del p.N494Tfs*10 | Frame Shift Del (DEL) | VAF 34/241 reads (14%) | called by mutect2, pindel, varscan2
- CACNA1F | c.3802G>A p.D1268N | Missense Mutation (SNP) | VAF 12/331 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC91 | c.1199T>C p.I400T | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CDC42BPG | c.2921G>T p.S974I | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CENPO | c.443T>A p.L148H | Missense Mutation (SNP) | VAF 68/462 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DST | c.1552C>G p.L518V (on ENST00000361203 / NM_001374722.1; = p.L192V on NM_001723.6) | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAHD1 | c.580A>G p.K194E | Missense Mutation (SNP) | VAF 77/343 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FDPS | c.890T>C p.I297T | Missense Mutation (SNP) | VAF 59/298 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- G2E3 | c.917C>A p.S306Y | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- G6PC | c.746_751del p.E249_W250del | In Frame Del (DEL) | VAF 50/207 reads (24%) | called by mutect2, pindel, varscan2
- GALNS | c.308A>C p.H103P | Missense Mutation (SNP) | VAF 80/500 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- GALNT3 | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 75/413 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPAA1 | c.1247T>A p.L416H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK2 | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- HDAC1 | c.1088dup p.Q364Tfs*5 | Frame Shift Ins (INS) | VAF 32/187 reads (17%) | called by mutect2, pindel, varscan2
- IL17RD | c.1841G>C p.G614A | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA3 | c.1484T>G p.L495R | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ITGB7 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- JUP | c.746C>G p.T249R | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCP | c.3848G>A p.C1283Y (on ENST00000620378; = p.C1407Y on NM_001366122.1) | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRTAP1-4 | c.9C>G p.S3R | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MGA | c.6023_6024del p.I2008Kfs*15 (on ENST00000219905 / NM_001164273.1; = p.I1799Kfs*15 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 50/200 reads (25%) | called by mutect2, pindel, varscan2
- MKS1 | c.1286T>C p.L429P | Missense Mutation (SNP) | VAF 69/352 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- MTX1 | c.838A>C p.M280L | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NID1 | c.571T>G p.Y191D | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- NIPBL | c.6216T>G p.D2072E | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- PALB2 | c.1355A>C p.N452T | Missense Mutation (SNP) | VAF 82/385 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- PAPOLA | c.1558G>T p.D520Y | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.982A>T p.M328L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PPM1J | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PRAMEF1 | c.943C>A p.Q315K | Missense Mutation (SNP) | VAF 103/504 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PTPRD | c.3673T>A p.Y1225N | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SETD2 | c.2962G>T p.G988* | Nonsense Mutation (SNP) | VAF 47/173 reads (27%) | called by muse, mutect2, varscan2
- SLC16A1 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 55/332 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SLC26A1 | c.1955C>G p.P652R | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- STIP1 | c.371T>C p.F124S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SYNE1 | c.24748T>G p.S8250A (on ENST00000367255 / NM_182961.4; = p.S8179A on NM_033071.3) | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- TEKT1 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TKT | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- TRAV6 | c.288A>C p.K96N | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRPC7 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPV2 | c.1421+7G>A | Splice Region (SNP) | VAF 40/218 reads (18%) | called by muse, mutect2, varscan2
- TTC39B | c.1180C>A p.L394I | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- UGT8 | c.1390G>C p.V464L | Missense Mutation (SNP) | VAF 53/350 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- USH2A | c.13087G>T p.D4363Y | Missense Mutation (SNP) | VAF 12/379 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.273); called by muse, mutect2
- ZNF140 | c.1192T>C p.F398L | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZSWIM8 | c.5068T>A p.F1690I (on ENST00000605216 / NM_001242487.2; = p.F1695I on NM_015037.3) | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZSWIM8 | c.5069T>A p.F1690Y (on ENST00000605216 / NM_001242487.2; = p.F1695Y on NM_015037.3) | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- AL157392.5 | c.606G>T p.S202= | Silent (SNP) | VAF 45/216 reads (21%) | catalogued as rs754563506, COSV62265255; called by muse, mutect2, varscan2
- C3orf20 | c.558G>A p.E186= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as rs779781802; called by muse, mutect2, varscan2
- CDH17 | c.1251G>A p.Q417= | Silent (SNP) | VAF 58/234 reads (25%) | called by muse, mutect2, varscan2
- NKTR | c.4035A>G p.T1345= | Silent (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2
- NUP188 | c.2832C>T p.G944= | Silent (SNP) | VAF 82/337 reads (24%) | called by muse, mutect2, varscan2
- PRPF4B | c.678A>G p.P226= | Silent (SNP) | VAF 54/315 reads (17%) | catalogued as rs771154834; called by muse, mutect2, varscan2
- RNF207 | c.528C>A p.I176= | Silent (SNP) | VAF 77/460 reads (17%) | called by muse, mutect2, varscan2
- SEZ6L2 | c.2277T>C p.D759= (on ENST00000308713 / NM_001114099.3; = p.D689= on NM_012410.4) | Silent (SNP) | VAF 47/283 reads (17%) | called by muse, mutect2, varscan2
- SHPRH | c.816C>T p.D272= | Silent (SNP) | VAF 35/346 reads (10%) | called by muse, mutect2, varscan2
- TRIP12 | c.1227G>A p.R409= | Silent (SNP) | VAF 38/216 reads (18%) | called by muse, varscan2
- USP46 | c.129A>G p.T43= | Silent (SNP) | VAF 36/131 reads (27%) | catalogued as rs748842503; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826681 T>C | 3'Flank (SNP) | VAF 97/222 reads (44%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502631 CTATAGA>TTTTTGG | 5'Flank (ONP) | VAF 3/37 reads (8%) | called by muse*, pindel, varscan2*
- C5orf60 | n.1761C>T | RNA (SNP) | VAF 124/653 reads (19%) | catalogued as rs545388718; called by muse, mutect2, varscan2
- CLCN7 | c.981+51C>T | Intron (SNP) | VAF 52/282 reads (18%) | called by muse, mutect2, varscan2
- FMR1 | c.1189-42A>G | Intron (SNP) | VAF 47/125 reads (38%) | catalogued as rs375873377; called by muse, mutect2, varscan2
- GNB5 | c.127-15C>T | Intron (SNP) | VAF 82/361 reads (23%) | called by muse, mutect2, varscan2
- KANSL2 | c.431-72_431-62del | Intron (DEL) | VAF 35/217 reads (16%) | called by mutect2, pindel, varscan2
- MIR145 | chr5:149428900 G>A | 5'Flank (SNP) | VAF 55/330 reads (17%) | called by muse, mutect2, varscan2
- MKS1 | chr17:58219464 del A | 5'Flank (DEL) | VAF 44/246 reads (18%) | called by mutect2, pindel, varscan2
- PRRT1 | c.20-60T>A | Intron (SNP) | VAF 79/373 reads (21%) | called by muse, mutect2, varscan2
- RASSF4 | c.63-114A>G | Intron (SNP) | VAF 41/186 reads (22%) | catalogued as rs1202989137; called by muse, mutect2, varscan2
- SERF2 | c.*112T>A | 3'UTR (SNP) | VAF 34/161 reads (21%) | called by muse, mutect2, varscan2
- WARS1 | c.99+3022G>T | Intron (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
